Gene-level copy-number profile of tumor specimen HTMCP-01-06-00422-01A from CGCI case HTMCP-01-06-00422, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: female; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 51.3 years (18,737 days).
Specimen HTMCP-01-06-00422-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file be6c61e3-56c9-40f4-be73-6f5fa02c586f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00422-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/cf753c35-fedd-4f17-a1e2-b71a56dc50c7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 5,306; copy number 2: 48,944; copy number 3: 3,460; copy number 4: 598.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,413,766–116,706,603, 12 genes (within-gene range 0–1): RNU6-817P, LINC01762, AL136376.1, Y_RNA, AL390066.1, AL390066.2, CD58, NAP1L4P1, MIR548AC, IGSF3, MIR320B1, LINC02868.
- chr2:88,811,186–88,861,563, 3 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A.
- chr4:81,426,393–82,402,706, 13 genes: RASGEF1B, MTCYBP44, COX5BP1, AC021863.1, NPM1P41, HNRNPA3P13, RNU6-499P, BIN2P1, AC124016.2, HNRNPD, AC124016.1, IGBP1P4, SNORD42.
- chr4:88,007,635–88,730,103, 26 genes (within-gene range 0–1): PKD2, ABCG2, AC097484.1, RNU6-818P, RNU6ATAC31P, AC097484.2, RNU6-1298P, PPM1K, RNU6-112P, PPM1K-DT, Y_RNA, HERC6, HERC5, NCOA4P2, PYURF, PIGY, AC098582.1, PIGY-DT, AC083829.1, RN7SKP244, HERC3, RNU6-33P, NAP1L5, FAM13A-AS1, AC108065.2, AC108065.1.
- chr14:105,785,505–105,845,678, 2 genes (within-gene range 0–2): ATP6V1G1P1, IGHD.
- chr14:105,857,513–105,857,572, 1 gene (within-gene range 0–2): MIR4539.
- chr14:105,858,165–105,916,856, 38 genes (within-gene range 0–2): MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,962. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
